TCGA case TCGA-76-6280 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Thomas Jefferson University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ccc0eda-96f8-475c-9d8c-016b26fdd81d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 346 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,931 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 66 days; Treatment dose: 60 cGy; Number of fractions: 23; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 182 days; Days to treatment end: 192 days; Treatment dose: 35 cGy; Number of fractions: 10; Treatment anatomic sites: Primary Tumor Field.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 57.6 years (21,039 days); Days to diagnosis: 108 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 136 days.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 108 (post initial treatment): Progression or recurrence: Yes; Days to progression: 108 days.
- Days to follow up: 346 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-76-6280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-76-6280-01A-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 0.
- Sample TCGA-76-6280-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment: Pharmaceutical therapy drug name: Temodar.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 346 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 346 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 108 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-76-6280-01A-21D-1842-01): tumor purity 0.79, ploidy 2.02, whole-genome doublings 0.
